Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A8LN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A8LN-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Melanoma 8720/3

Site: Pelvic lymph node
C77.5

JW 11/24/13

SPECIMENS:

- A. RIGHT AXILLARY SLN #1
- B. RIGHT AXILLARY SLN #2
- C. WIDE EXCISION ANTERIOR RIGHT CHEST MELANOMA
- D. ADDITIONAL LATERAL MARGIN
- E. ADDITIONAL MEDIAL MARGIN

SPECIMEN(S):

- A. RIGHT AXILLARY SLN #1
- B. RIGHT AXILLARY SLN #2
- C. WIDE EXCISION ANTERIOR RIGHT CHEST MELANOMA
- D. ADDITIONAL LATERAL MARGIN
- E. ADDITIONAL MEDIAL MARGIN

DIAGNOSIS:

- A. SENTINEL LYMPH NODE, RIGHT AXILLA #1, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
- SEE CONFIRMATORY STAIN TABLE
- B. SENTINEL LYMPH NODE, RIGHT AXILLA #2, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR MELANOMA (0/1)
- SEE CONFIRMATORY STAIN TABLE
- C. SKIN OF ANTERIOR RIGHT CHEST, EXCISION:
- RESIDUAL ULCERATED MALIGNANT MELANOMA.
- RESIDUAL IS BRESLOW DEPTH 5.8 MM
- MARGINS ARE NEGATIVE FOR MELANOMA
- SEE COMMENT
- BIOPSY SITE CHANGES
- D. SKIN OF RIGHT CHEST, ADDITIONAL LATERAL MARGIN, EXCISION:
- NEGATIVE FOR MELANOMA
- E. SKIN OF RIGHT CHEST, ADDITIONAL MEDIAL MARGIN, EXCISION:
- NEGATIVE FOR MELANOMA.

COMMENT: The residual melanoma has some "small cell" morphologic features. Although deeper than seen in the original biopsy (), this does not impact staging.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material:

Population: Sentinel lymph node

Stain/Marker:Result: Comment:

S-100 Negative Internal control cells positive in all nodes.
A103,MELAN-A Negative

Material

Population: Sentinel lymph node

Stain/Marker:Result: Comment:

S-100 Negative
A103,MELAN-A Negative

Material:

Population: Sentinel lymph node

[page 2 of 3]
Stain/Marker:Result: Comment:
S-100 Negative
A103,MELAN-A Negative

Material:
Population: Sentinel lymph node

Stain/Marker:Result: Comment:
S-100 Negative
A103,MELAN-A Negative

Material:
Population: Sentinel lymph node

Stain/Marker:Result: Comment:
S-100 Negative
A103,MELAN-A Negative

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the . The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

GROSS DESCRIPTION:

A. RIGHT AXILLARY SLN #1

Received fresh labeled with the patient's identification and "right axillary SLN #1" is a 5.2 x 2.2 x 0.9 cm lymph node. It is sectioned and has a peripheral area of red-brown discoloration. The remainder has a yellow-tan fatty cut surface; submitted entirely, A1-A4.

B. RIGHT AXILLARY SLN #2

Received fresh labeled with the patient's identification and "right axillary SLN #2" is a 2.9 x 2.2 x 1.3 cm piece of soft tissue containing a 2.2 x 1.6 x 0.9 cm lymph node. The lymph node is sectioned and has a peripheral area of red-tan coloration and the remainder is yellow-tan; lymph node is submitted entirely, B1.

C. WIDE EXCISION ANTERIOR RIGHT CHEST MELANOMA

Received fresh labeled with the patient's identification and "wide excision anterior chest melanoma" is an oval shaped piece of tan skin, 8 x 6 cm excised to a depth of 4 cm with a suture designating the lateral/12:00 position. There is a mottled brown-tan-black mass, 4.2 x 3 x 1 cm, located 1.5 cm from the closest/inferior margin. The superior margin is inked blue, inferior orange, and deep black. On sectioning, it grossly appears to superficial depth of invasion. A photograph is taken and tissue is procured; representatively submitted:

C1-C12: shave of entire margin submitted clockwise from 12:00 position

C13-C16: mass

C17-C21: perpendicular sections of entire deep margin, subjacent to lesion, lateral to medial

D. ADDITIONAL LATERAL MARGIN

[page 3 of 3]
Received fresh labeled with the patient's identification and "additional lateral margin" is a triangular shaped piece of tan skin, 6 x 3 cm excised to a depth of 3 cm with a suture designating the final lateral margin. The skin surface is unremarkable. The superior margin is inked blue inferior orange, and old surgical margin green. Sectioning reveals no discrete lesions; representatively submitted:

D1: lateral tip

D2-D3: shave of old surgical margin

E. ADDITIONAL MEDIAL MARGIN

Received fresh labeled with the patient's identification and "additional medial margin" is a triangular shaped piece of tan skin, 6.5 x 3 cm excised to a depth of 1.3 cm with a suture designating the final medial margin. Skin surface has a smooth purple-tan papule, 0.4 x 0.4 x 0.1 cm located 0.5 cm from the previous surgical margin. It has superficial depth of invasion; representatively submitted:

E1: new medial tip

E2-E3: shave of previous surgical margin

E4: purple-tan papule with margins

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

None Given

Gross Dictation:

Microscopic/Diagnostic Dictation: Pathologist

Final Review: Pathologist

Final: Pathologist

*TCGA tumor is from
Reaction after biopsy.*

Diagnosis Discrepancy	fw 11/19/13	
ICDPA Discrepancy		☒
Dual/Synchronous Primary Not d		☒

Source: NCI Genomic Data Commons file edcb8d77-b724-472f-9108-94414460b182 (TCGA-GN-A8LN.D6200075-438B-4BB6-A5A1-E1919FBEF131.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).